Gene-level copy-number profile of tumor specimen ALCH-B36Z-TTP1-A from ALCHEMIST case ALCH-B36Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.5 years (22,810 days).
Specimen ALCH-B36Z-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f862ce2c-a66f-4db6-8950-0e4443542169.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36Z-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/a751b3d2-14f0-4904-a894-febdb4f38ef2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 1,078; copy number 2: 10,174; copy number 3: 16,722; copy number 4: 21,139; copy number 5: 5,845; copy number 6: 2,729; copy number 7: 535; copy number 8: 177; copy number 9: 132; copy number 10: 28; copy number 11: 159; copy number 12: 10; copy number 13: 1; copy number 14: 38; copy number 16: 15; copy number 18: 28; copy number 21: 21; copy number 24: 35; copy number 25: 5.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:89,776,981–89,782,582, 1 gene: TRIM64DP.
- chr11:89,883,927–89,889,991, 2 genes: AP005435.4, AP005435.2.
- chr19:10,553,085–10,566,031, 1 gene (within-gene range 0–2): KRI1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 472 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,517,647, 1 gene, copy number 9: UGT2B29P.
- chr9:88,627,063–89,178,818, 8 genes, copy number 21: LINC02843, AL390791.1, MIR4289, PCNPP2, AL772202.1, S1PR3, SHC3, AL353150.1.
- chr9:89,605,012–92,325,636, 52 genes, copy number 13–21 (within-gene range 6–21): GADD45G, UNQ6494, BX470209.2, BX470209.1, AL161629.1, MIR4290HG, MIR4290, IL6RP1, AL161629.2, AL353649.1, OR7E31P, OR7E116P, LINC01508, LINC01501, DIRAS2, OR7E109P, OR7E108P, SYK, AL355607.1, AL355607.2, AL158071.3, AL158071.2, LINC00484, LINC00484, AL158071.1, AL158071.4, AUH, NFIL3, AL353764.1, ROR2, PAICSP2, MIR3910-1, MIR3910-2, SPTLC1, AL391219.1, HSPE1P22, AL354751.3, MTATP6P29, MTCO3P29, MTND3P23, MTND4LP7, MTND4P15, AL354751.1, LINC00475, AL354751.2, BEND3P2, PRSS47, AL136097.2, IARS1, MIR3651, SNORA84, NOL8.
- chr9:92,711,363–93,085,133, 12 genes, copy number 9: BICD2, AL136981.4, ANKRD19P, RNU6-714P, EEF1DP2, AL136981.2, ZNF484, AL136981.1, SNX18P2, ALOX15P2, FGD3, SUSD3.
- chr11:89,854,953–89,876,017, 3 genes, copy number 12: TRIM51BP, AP005435.1, TRIM64B.
- chr15:21,017,800–21,020,851, 2 genes, copy number 11: IGHD1OR15-1B, FAM30C.
- chr15:21,328,380–21,946,641, 35 genes, copy number 24: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2.
- chr15:21,980,277–21,981,245, 1 gene, copy number 11: OR11J6P.
- chr15:32,175,247–32,186,475, 2 genes, copy number 10: Y_RNA, AC068448.1.
- chr15:32,359,538–32,367,784, 1 gene, copy number 9: AC139426.2.
- chr18:22,699,481–27,595,164, 90 genes, copy number 9–11 (broad region; genes not listed).
- chr19:23,222,755–23,274,221, 1 gene, copy number 18 (within-gene range 2–18): AC092329.3.
- chr19:23,255,053–24,163,425, 34 genes, copy number 10–25: IPO5P1, AC092329.1, AC092329.4, VN1R90P, VN1R91P, ZNF91, AC010300.1, BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr20:20,389,530–21,425,041, 20 genes, copy number 11: RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140.
- chr20:22,054,074–23,132,635, 21 genes, copy number 12–16: LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656.
- chr20:45,823,214–46,459,276, 27 genes, copy number 11: TNNC2, SNX21, ACOT8, Metazoa_SRP, ZSWIM3, ZSWIM1, SPATA25, NEURL2, CTSA, AL008726.1, PLTP, AL162458.1, PCIF1, ZNF335, FTLP1, MMP9, SLC12A5-AS1, SLC12A5, NCOA5, RPL13P2, CD40, AL031687.1, CDH22, SLC35C2, AL133227.1, ELMO2, ZNF663P.
- chr20:46,463,719–46,477,232, 1 gene, copy number 11: MKRN7P.
- chr20:49,113,339–49,188,367, 1 gene, copy number 12 (within-gene range 3–12): STAU1.
- chr20:52,972,358–53,634,590, 13 genes, copy number 10: TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1.
- chr20:54,153,446–54,651,169, 4 genes, copy number 9: CYP24A1, PFDN4, AL133335.1, DOK5.
- chr20:60,755,001–62,685,785, 48 genes, copy number 11: AL117372.1, AL139348.1, AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1.
- chr20:62,774,121–64,327,972, 95 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 421. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
